Gene-level copy-number profile of tumor specimen SM-JU353 from CPTAC case C247230, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G4.
Specimen SM-JU353: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f54df44d-ecb3-4225-9ef0-02a1b8dda2f3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105280 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/d31dcbb0-4358-4063-82f3-f9ac08e56eda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 5,375; copy number 2: 50,350; copy number 3: 3,108; copy number 4: 13.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,106,543–25,089,151, 66 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,519. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
